Gene-level copy-number profile of tumor specimen TCGA-77-8009-01A from TCGA case TCGA-77-8009, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.5 years (25,037 days).
Specimen TCGA-77-8009-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.12031677-4ed7-42ac-a61a-3866b5a1cba1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8009-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/115b05cd-f095-4197-b953-7ab17c1455e3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 8,298; copy number 2: 20,316; copy number 3: 18,970; copy number 4: 8,634; copy number 5: 1,004; copy number 6: 1,016; copy number 7: 139; copy number 8: 179; copy number 9: 438; copy number 10: 328; copy number 11: 240; copy number 12: 22; copy number 13: 17; copy number 14: 7; copy number 15: 114; copy number 16: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8009-01A-11D-2183-01): tumor purity 0.67, ploidy 5.7, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,335,608–41,381,832, 2 genes: NCR2, AL136967.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,567 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:49,878,623–51,225,575, 8 genes, copy number 8 (within-gene range 5–8): RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1.
- chr2:66,574,030–69,942,945, 61 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:152,243,828–198,222,513, 804 genes, copy number 9–16 (broad region; genes not listed).
- chr4:64,914,281–65,241,814, 5 genes, copy number 9: LINC02232, AC107058.1, EFL1P2, AC096754.1, LINC02835.
- chr7:63,011,463–66,649,067, 173 genes, copy number 7–8 (broad region; genes not listed).
- chr7:66,654,538–66,671,523, 1 gene, copy number 8: AC006001.2.
- chr8:104,590,733–105,804,539, 1 gene, copy number 7 (within-gene range 6–7): ZFPM2.
- chr8:105,142,860–106,770,244, 17 genes, copy number 7: AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA.
- chr9:34,179,005–34,252,523, 1 gene, copy number 9 (within-gene range 1–9): UBAP1.
- chr9:34,223,984–35,907,136, 96 genes, copy number 9 (broad region; genes not listed).
- chr11:69,294,151–79,441,030, 313 genes, copy number 9–15 (within-gene range 2–15) (broad region; genes not listed).
- chr11:89,731,017–91,234,388, 57 genes, copy number 7: AP003122.5, UBTFL2, AP003122.2, AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49, AP004833.1, TRIM53BP, TRIM51BP, AP005435.1, TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1, TRIM49D2, AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1, AP000648.2, AP000648.9, AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1, DISC1FP1, TUBAP2, MIR4490, AP002782.1, MIR1261, AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1.
- chr19:10,133,342–10,587,315, 30 genes, copy number 11 (within-gene range 4–11): DNMT1, S1PR2, MIR4322, MRPL4, AC011511.2, AC011511.3, ICAM1, AC011511.5, ICAM4, ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3, TYK2, CDC37, MIR1181, PDE4A, KEAP1, AC011461.1, S1PR5, ATG4D, RNU7-140P, MIR1238, KRI1, CDKN2D, AP1M2.

Autosomal genes at a single copy (total copy number 1): 7,414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
